Somatic mutation profile of tumor specimen 0DK0AH from CCDI case PBBXLT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lymph nodes of multiple regions; Age at diagnosis: 17.2 years (6,298 days).
Specimen 0DK0AH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f7094af-dcd3-4c49-ad50-da3990be1a58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK0AO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fa0df45-c6cb-45ce-a379-2564530fcbc5

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 3, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP5 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 137/1185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369146124; called by muse, mutect2, varscan2
- GAS7 | c.1300G>A p.D434N (on ENST00000432992 / NM_201433.2; = p.D294N on NM_003644.3) | Missense Mutation (SNP) | VAF 153/951 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.293); catalogued as COSV100097367; called by muse, mutect2, varscan2
- MUC12 | c.10087G>A p.V3363I (on ENST00000379442; = p.V3220I on NM_001164462.1) | Missense Mutation (SNP) | VAF 164/2985 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.101); catalogued as rs1484207631, COSV65210128; called by muse, mutect2
- CCNQ | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 129/858 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MECR | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 348/836 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.051); called by muse, varscan2
- NRXN2 | c.2115T>G p.C705W | Missense Mutation (SNP) | VAF 177/477 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PREX2 | c.2012G>T p.S671I | Missense Mutation (SNP) | VAF 239/1135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- UPF1 | c.*3+2C>T | Splice Site (SNP) | VAF 152/367 reads (41%) | called by muse, mutect2, varscan2
- ABCC9 | c.4320G>A p.A1440= | Silent (SNP) | VAF 300/989 reads (30%) | catalogued as rs377289768; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPB41L4B | c.1317A>G p.K439= | Silent (SNP) | VAF 286/794 reads (36%) | called by muse, mutect2, varscan2
- PCDHB14 | c.825A>G p.G275= | Silent (SNP) | VAF 329/764 reads (43%) | called by muse, mutect2, varscan2
- QRICH2 | c.3568C>T p.L1190= | Silent (SNP) | VAF 270/927 reads (29%) | called by muse, mutect2, varscan2
- STAT3 | c.1179G>A p.V393= | Silent (SNP) | VAF 487/1716 reads (28%) | called by muse, mutect2, varscan2
- CLASRP | c.613+92C>T | Intron (SNP) | VAF 30/141 reads (21%) | catalogued as rs532360815; called by muse, mutect2, varscan2
- FAM236D | c.*31C>T | 3'UTR (SNP) | VAF 72/1341 reads (5%) | catalogued as rs1213339635; called by muse, mutect2
- GNL3 | c.655-50G>A | Intron (SNP) | VAF 175/366 reads (48%) | called by muse, mutect2, varscan2
- TMCO1 | c.223+167A>T | Intron (SNP) | VAF 287/1139 reads (25%) | called by muse, mutect2, varscan2
